CCDI case PBCDTI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b9056a96-503a-4b35-a3e0-367a715a61b0

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.0 years (3,290 days).

Biospecimens (3 samples)
- Sample 0DPJSD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPJSO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPJSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
